Somatic mutation profile of tumor specimen TCGA-VS-A9UL-01A (aliquot TCGA-VS-A9UL-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 79.5 years (29,033 days).
Specimen TCGA-VS-A9UL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dfc5c1c-4a10-4961-ba17-6655377496b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UL-10A (Blood Derived Normal), aliquot TCGA-VS-A9UL-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/705605bd-db54-4cad-9dfe-53ba7d99a609

The open-access MAF lists 143 somatic variants for this specimen: 100 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 39, Nonsense Mutation 8, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, 5'Flank 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4398G>C p.W1466C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54327842, COSV54327957, COSV54334788; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 91/219 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.8629C>T p.P2877S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs944893421, COSV101447091; called by muse, mutect2, varscan2
- ABCC9 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99685034; called by muse, mutect2
- ACSBG2 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.374); catalogued as COSV99397547; called by muse, mutect2, varscan2
- ACTN4 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1186360472, COSV99400550; called by muse, mutect2, varscan2
- ADNP | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100823808; called by muse, mutect2, varscan2
- ALPK2 | c.4441C>T p.Q1481* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100864601; called by muse, mutect2, varscan2
- AMOT | c.1774G>T p.E592* (on ENST00000371959 / NM_001113490.1; = p.E183* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100495369; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2, varscan2
- ARHGAP4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100604160; called by muse, mutect2, varscan2
- ASTN2 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs1265432305, COSV100527343, COSV57808036; called by muse, mutect2, varscan2
- ATP5F1C | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100184366; called by muse, mutect2
- BICRAL | c.2917C>T p.Q973* | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100018310; called by muse, mutect2
- BRWD1 | c.6281G>A p.R2094H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.732); catalogued as rs766937547, COSV60902182; called by muse, mutect2, varscan2
- CDH17 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954084184, COSV50342406; called by muse, mutect2, varscan2
- CDH18 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 120/207 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as rs750768779, COSV56917098; called by muse, mutect2, varscan2
- CELSR2 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99604443; called by muse, mutect2, varscan2
- CMTM5 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs751980986, COSV100198143; called by muse, mutect2, varscan2
- COX11 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV100174066; called by muse, mutect2, varscan2
- CR2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs147633291; called by muse, mutect2, varscan2
- CSF2RB | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs759239121, COSV99454213; called by muse, varscan2
- CUL7 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs1191207102, COSV54813885; called by muse, mutect2, varscan2
- DNAH3 | c.9872G>A p.R3291Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761883403, COSV99765130; called by muse, mutect2, varscan2
- DOP1B | c.4651G>A p.D1551N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.07); catalogued as COSV101215669; called by muse, mutect2, varscan2
- DSP | c.5698G>A p.E1900K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.66); catalogued as rs751447598, COSV101131561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYRK1A | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100118140; called by muse, mutect2, varscan2
- EEA1 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs1434554778, COSV100468219; called by muse, mutect2, varscan2
- EFCAB13 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs763879131, COSV58946331; called by muse, mutect2, varscan2
- ENDOV | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs1223292679, COSV100108604; called by muse, mutect2, varscan2
- EXOC3L2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV52972841; called by muse, mutect2, varscan2
- FAM71F1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.197); catalogued as rs1301373523, COSV100171089; called by muse, mutect2, varscan2
- FLG | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV100911886, COSV64246099; called by muse, mutect2, varscan2
- FLG2 | c.4898C>G p.S1633C | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV66167574; called by muse, mutect2, varscan2
- FRAS1 | c.4715C>T p.S1572L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99354380; called by muse, mutect2, varscan2
- GPD2 | c.422T>A p.L141H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100133493; called by muse, mutect2
- GPRASP1 | c.3166C>A p.P1056T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100851048, COSV64356245; called by muse, mutect2, varscan2
- IGKV6D-21 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777425934; called by muse, mutect2, varscan2
- IKZF2 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100563726; called by muse, mutect2
- KCTD13 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442214; called by muse, mutect2, varscan2
- LAPTM5 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs747955844, COSV99612563; called by muse, mutect2, varscan2
- LINGO1 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1219832893, COSV100796462; called by muse, mutect2, varscan2
- MAN2A2 | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552386397, COSV100847789; called by muse, mutect2, varscan2
- MASP1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99397462; called by muse, mutect2
- MBOAT7 | c.1063T>G p.W355G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99824940; called by muse, mutect2, varscan2
- MFN1 | c.639G>C p.M213I | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99764609; called by muse, mutect2
- MIA3 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1282989197, COSV60512038; called by muse, mutect2, varscan2
- MRPL44 | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99285281; called by muse, mutect2, varscan2
- MTHFS | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99358288; called by muse, varscan2
- MTMR1 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV64892948; called by muse, mutect2, varscan2
- MXRA5 | c.4274C>T p.S1425F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV99478282; called by muse, mutect2, varscan2
- MYOM2 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as rs201853007, COSV100036536; called by muse, mutect2, varscan2
- NAV2 | c.3107C>G p.S1036C (on ENST00000396087 / NM_001244963.2; = p.S1013C on NM_145117.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100217397; called by muse, mutect2, varscan2
- NCKAP1L | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867197350, COSV53203951; called by muse, mutect2, varscan2
- NME4 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs372887454; called by muse, varscan2
- NUDT22 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV99655972; called by muse, mutect2, varscan2
- OTOP2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs145474317; called by muse, mutect2, varscan2
- PELI3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); catalogued as rs541571878, COSV57856057; called by muse, mutect2, varscan2
- PEX5L | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99829445; called by muse, mutect2
- PF4V1 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV99896369; called by mutect2, varscan2
- PHF14 | c.2275C>T p.L759F | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68857743; called by muse, mutect2, varscan2
- PID1 | c.6G>A p.W2* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101237167; called by muse, mutect2, varscan2
- PLCD1 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as rs779608157, COSV52185303; called by muse, mutect2, varscan2
- PLPP4 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100956470; called by muse, mutect2, varscan2
- POTEE | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs549330020, COSV100388529; called by muse, mutect2, varscan2
- POU4F3 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV100047179, COSV57944463; called by mutect2, varscan2
- PYGM | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200038732, CM076452, COSV51215131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPA4 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61285823; called by muse, mutect2
- SATB1 | c.2111G>A p.G704D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs1179666041; called by muse, mutect2
- SETD1A | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs747410617, COSV99353455; called by muse, varscan2
- SGO2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV100764609; called by muse, mutect2, varscan2
- SHROOM2 | c.3127G>T p.A1043S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV101098908; called by muse, mutect2, varscan2
- SIRPD | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs561939776, COSV101064901, COSV101064972; called by muse, mutect2, varscan2
- SLC26A11 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV58338420; called by muse, mutect2, varscan2
- SLC36A2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs768169962, COSV100079062; called by muse, mutect2, varscan2
- SLC4A11 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs761571805, COSV101195935; called by muse, mutect2, varscan2
- SLCO5A1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs776943828, COSV52653397; called by muse, mutect2, varscan2
- SPATC1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs377636679, COSV101085182; called by muse, mutect2, varscan2
- SPHKAP | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs370506646, COSV60891745; called by muse, mutect2, varscan2
- SPTA1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs565907779, COSV63749834, COSV63750786; called by muse, mutect2, varscan2
- STX5 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs761425627, COSV99586266; called by muse, mutect2, varscan2
- SYNE2 | c.8146T>A p.L2716M | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100648196; called by muse, mutect2, varscan2
- TET3 | c.3367G>C p.E1123Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101327997; called by muse, mutect2, varscan2
- TF | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs144129858; called by muse, mutect2, varscan2
- TFRC | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs370784605; called by muse, mutect2, varscan2
- TMPRSS11D | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369417549; called by muse, varscan2
- TOPBP1 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99605626; called by muse, mutect2, varscan2
- TPTE | c.1067C>T p.S356F (on ENST00000618007 / NM_199261.4; = p.S338F on NM_199259.4) | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1162654957; called by muse, mutect2
- UQCRFS1 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100508143; called by muse, mutect2, varscan2
- WAC | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1412555875, COSV100611149; called by muse, mutect2, varscan2
- WASHC4 | c.545C>A p.T182N | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100162616; called by muse, mutect2, varscan2
- YRDC | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs763656759, COSV100203951; called by muse, mutect2, varscan2
- ZBTB20 | c.505G>A p.E169K (on ENST00000474710 / NM_001164342.2; = p.E96K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100614571; called by muse, mutect2
- ZBTB38 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs746523617, COSV100375862; called by muse, mutect2, varscan2
- ZIM2 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.5); catalogued as COSV99689819; called by muse, mutect2, varscan2
- ZNF184 | c.1035G>C p.Q345H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV53003800; called by muse, mutect2
- ITGBL1 | c.1133-7_1140del p.X378_splice | Splice Site (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- PCYT1A | c.453_471dup p.L158Dfs*13 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | called by mutect2, varscan2
- TCEAL4 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- TRAV17 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- AC023055.1 | c.1434C>T p.S478= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100278621; called by muse, mutect2, varscan2
- ANKRD42 | c.573G>A p.T191= | Silent (SNP) | VAF 57/96 reads (59%) | catalogued as rs145591736; called by muse, mutect2, varscan2
- ANKZF1 | c.1275G>A p.L425= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99850758; called by muse, mutect2, varscan2
- ASB4 | c.729C>T p.A243= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1387140013, COSV57943009; called by muse, mutect2, varscan2
- BAHCC1 | c.4564C>T p.L1522= | Silent (SNP) | VAF 58/100 reads (58%) | catalogued as COSV100311907; called by muse, mutect2, varscan2
- C12orf66 | c.48G>A p.A16= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs768340479, COSV100320731; called by muse, mutect2, varscan2
- C6 | c.2442C>T p.P814= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs766437646, COSV54711019, COSV99667504; called by muse, mutect2
- CD8B | c.591G>A p.R197= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100514632; called by muse, mutect2, varscan2
- CNGA2 | c.1209G>A p.K403= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100323841; called by muse, mutect2, varscan2
- CNTRL | c.3240G>A p.L1080= | Silent (SNP) | VAF 72/100 reads (72%) | catalogued as COSV99443192, COSV99443896; called by muse, mutect2, varscan2
- CTAGE6 | c.780T>C p.N260= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV101417866; called by mutect2, varscan2
- DNMT3B | c.2139C>T p.F713= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs752571603, COSV99142699; ClinVar: likely benign; called by muse, mutect2, varscan2
- DRP2 | c.1258C>T p.L420= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100871992; called by muse, mutect2
- FHOD1 | c.1326G>A p.R442= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99264345; called by muse, mutect2, varscan2
- HAO1 | c.534G>A p.P178= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs750852016, COSV66492678; called by muse, mutect2, varscan2
- HCN1 | c.1800T>C p.I600= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100301447; called by muse, mutect2
- IGKV1-12 | c.51C>T p.F17= | Silent (SNP) | VAF 29/300 reads (10%) | catalogued as rs1226563621; called by muse, mutect2
- KCNG3 | c.255C>T p.F85= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs1285138887, COSV60148332; called by muse, mutect2, varscan2
- KIAA0586 | c.1563C>T p.I521= (on ENST00000619416 / NM_001244190.2; = p.I536= on NM_014749.5) | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV99708564; called by muse, mutect2, varscan2
- MBOAT7 | c.982C>T p.L328= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99824943; called by muse, mutect2
- MYO3A | c.654C>T p.I218= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV56327831; called by muse, mutect2
- MYO5C | c.3087G>A p.L1029= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99955127; called by muse, mutect2
- NPHP4 | c.1977A>G p.G659= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100977073; called by muse, mutect2, varscan2
- OLFM3 | c.1143G>A p.V381= (on ENST00000338858 / NM_001288821.1; = p.V361= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100129848; called by muse, mutect2, varscan2
- PI4K2A | c.1233C>T p.F411= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs368596585; called by muse, mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs555559126, COSV74119824; called by mutect2, varscan2
- PLA2G12B | c.417G>A p.S139= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as rs970974552, COSV100888023; called by muse, mutect2, varscan2
- PRPF8 | c.2067G>A p.V689= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100517725; called by muse, mutect2, varscan2
- PSMA3 | c.498C>T p.I166= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs189216032; called by muse, varscan2
- RFC5 | c.222G>A p.A74= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs371346746; called by muse, mutect2, varscan2
- SLCO3A1 | c.447C>G p.V149= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100575733; called by muse, mutect2, varscan2
- SOWAHC | c.1341G>T p.G447= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100454228; called by muse, mutect2
- SPEN | c.10521C>T p.I3507= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs762228676, COSV65268153; called by muse, varscan2
- SSC4D | c.1608C>T p.L536= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99300082; called by muse, mutect2, varscan2
- SYNPO | c.2626C>T p.L876= (on ENST00000394243 / NM_001166208.2; = p.L632= on NM_007286.6) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100302300; called by muse, mutect2, varscan2
- TRABD | c.915G>A p.E305= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100326903; called by muse, mutect2, varscan2
- TRPC5 | c.2307C>T p.S769= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99462052; called by muse, mutect2, varscan2
- TTN | c.35091C>T p.V11697= (on ENST00000591111; = p.V10770= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV59913363; called by muse, mutect2, varscan2
- ZNF503 | c.591T>G p.G197= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs537117248, COSV100998032; called by muse, varscan2
- GNB1L | c.*1C>T | 3'UTR (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100284303; called by muse, mutect2, varscan2
- PPP2R2B | c.-3G>A | 5'UTR (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100355647; called by muse, mutect2, varscan2
- SON | c.6657+137G>A | Intron (SNP) | VAF 20/37 reads (54%) | catalogued as COSV99279291; called by muse, mutect2, varscan2
- UNC13A | chr19:17688204 C>T | 5'Flank (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101466517; called by muse, mutect2, varscan2
